Somatic mutation profile of tumor specimen TCGA-50-5946-02A (aliquot TCGA-50-5946-02A-11D-2107-08) from TCGA case TCGA-50-5946, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 62.6 years (22,852 days).
Specimen TCGA-50-5946-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 785f19dd-16f5-4330-914e-0b295835b4d2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5946-10A (Blood Derived Normal), aliquot TCGA-50-5946-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/697edfa6-87d8-49ea-ab54-c413ef80e900

The open-access MAF lists 762 somatic variants for this specimen: 557 protein-altering or splice-affecting, 189 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 480, Silent 189, Nonsense Mutation 34, Splice Site 16, Frame Shift Del 15, Intron 5, 3'UTR 4, Frame Shift Ins 4, RNA 4, Splice Region 4, In Frame Del 3, 3'Flank 2.

Variants (750 of 762; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>T p.G509V (on ENST00000288602 / NM_001374244.1; = p.G469V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/189 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CBL | c.1237G>C p.G413R | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371679886, COSV50631517, COSV50635110; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.6020T>C p.I2007T | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554204921, COSV61772206; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1615C>T p.R539C (on ENST00000297504 / NM_001282291.2; = p.R522C on NM_007188.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.302); catalogued as rs767522915, COSV99873809; called by muse, mutect2, varscan2
- ADAMTS12 | c.2665G>T p.G889W | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61276406; called by muse, mutect2, varscan2
- ADAMTS3 | c.1745+1G>T p.X582_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV54387112; called by muse, mutect2, varscan2
- ADD3 | c.2069G>A p.R690H (on ENST00000356080 / NM_001320591.2; = p.R658H on NM_001121.4) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as rs760132854, COSV53323336; called by muse, mutect2, varscan2
- ADGRF2 | c.1336C>A p.L446M (on ENST00000296862 / NM_001368115.2; = p.L378M on NM_153839.7) | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57287103; called by muse, mutect2, varscan2
- ADGRL2 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as COSV54656881; called by muse, mutect2, varscan2
- AFM | c.472C>A p.L158I | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.061); catalogued as rs1560409010, COSV56919059, COSV56919350; called by muse, mutect2, varscan2
- AGO1 | c.512+1G>T p.X171_splice | Splice Site (SNP) | VAF 24/90 reads (27%) | catalogued as COSV64594803; called by muse, mutect2, varscan2
- AHNAK2 | c.11665G>A p.V3889M | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.835); catalogued as rs373615265, COSV60909964; called by muse, mutect2, varscan2
- AHNAK2 | c.11541G>C p.K3847N | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV60909972; called by muse, mutect2, varscan2
- AIPL1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 37/42 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV51506185; called by muse, mutect2, varscan2
- AK8 | c.889G>T p.V297F | Missense Mutation (SNP) | VAF 62/124 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53751474; called by muse, mutect2, varscan2
- AKR1B15 | c.636G>T p.Q212H | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71151188; called by muse, mutect2, varscan2
- ALK | c.1120G>T p.E374* | Nonsense Mutation (SNP) | VAF 24/120 reads (20%) | catalogued as COSV66586819; called by muse, mutect2, varscan2
- ALOX12 | c.1795C>A p.R599S | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs757495245, COSV52348918, COSV52351528; called by muse, mutect2, varscan2
- AMACR | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 63/230 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); catalogued as COSV56870238; called by muse, mutect2, varscan2
- ANGPTL5 | c.733G>T p.V245L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as COSV57532216; called by muse, mutect2, varscan2
- ANK2 | c.11855C>T p.S3952L | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); catalogued as COSV99999805; called by muse, mutect2, varscan2
- ANKRD28 | c.2972C>G p.P991R | Missense Mutation (SNP) | VAF 96/157 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV67517226; called by muse, mutect2, varscan2
- ANKRD30A | c.995T>A p.V332E (on ENST00000611781; = p.V276E on NM_052997.2) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV64606072; called by muse, mutect2, varscan2
- ANO7 | c.1232T>A p.L411Q (on ENST00000274979; = p.L357Q on NM_001370694.2) | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.183); catalogued as COSV51469443; called by muse, mutect2, varscan2
- ANP32A | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV51189383; called by muse, mutect2, varscan2
- ANXA3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV53713734; called by muse, mutect2, varscan2
- APH1A | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 42/312 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52528410; called by muse, mutect2, varscan2
- APOBEC4 | c.982C>A p.Q328K | Missense Mutation (SNP) | VAF 31/147 reads (21%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as COSV58017029; called by muse, mutect2, varscan2
- ARHGAP33 | c.3115G>A p.G1039S | Missense Mutation (SNP) | VAF 57/119 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.121); catalogued as rs561150729, COSV50119719; called by muse, mutect2, varscan2
- ARID5B | c.782G>T p.R261I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54415908; called by muse, mutect2, varscan2
- ARMC4 | c.2433A>T p.Q811H | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.665); catalogued as rs755790914, COSV59458695, COSV59468507; called by muse, mutect2, varscan2
- ASAH1 | c.133G>C p.E45Q | Missense Mutation (SNP) | VAF 37/59 reads (63%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV50501508; called by muse, mutect2, varscan2
- ASPSCR1 | c.606G>T p.L202F | Missense Mutation (SNP) | VAF 11/12 reads (92%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as COSV60727607; called by muse, mutect2, varscan2
- ATP10B | c.192G>C p.R64S | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.086); catalogued as COSV58778046, COSV58778794; called by muse, mutect2, varscan2
- ATRNL1 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100746196, COSV61799218; called by muse, mutect2, varscan2
- ATRX | c.5911G>T p.D1971Y | Missense Mutation (SNP) | VAF 115/132 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV64872950, COSV64872993; called by muse, mutect2, varscan2
- BCHE | c.1432C>A p.L478M | Missense Mutation (SNP) | VAF 72/103 reads (70%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV52254461; called by muse, mutect2, varscan2
- BIN2 | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.388); catalogued as COSV57207587; called by muse, mutect2, varscan2
- BLNK | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as COSV56409502; called by muse, mutect2, varscan2
- BMI1 | c.356A>T p.D119V | Missense Mutation (SNP) | VAF 41/143 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV64958785; called by muse, mutect2, varscan2
- BOD1L1 | c.692A>T p.E231V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV50007852; called by muse, mutect2, varscan2
- BRCA2 | c.2290G>A p.E764K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.149); catalogued as COSV66449983; called by muse, mutect2, varscan2
- C2orf16 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 67/198 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV68645504; called by muse, mutect2, varscan2
- C4orf17 | c.532G>T p.D178Y | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58511134, COSV58513402; called by muse, mutect2, varscan2
- C4orf3 | c.34G>A p.D12N | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs775986774, COSV101208163, COSV67581580; called by muse, mutect2, varscan2
- C8B | c.945C>A p.Y315* | Nonsense Mutation (SNP) | VAF 6/45 reads (13%) | catalogued as COSV100980718, COSV64776734; called by muse, mutect2, varscan2
- C9 | c.370G>A p.D124N | Missense Mutation (SNP) | VAF 242/363 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54675037; called by muse, mutect2, varscan2
- CABP1 | c.724G>A p.D242N (on ENST00000316803 / NM_001033677.1; = p.D39N on NM_004276.5) | Missense Mutation (SNP) | VAF 51/59 reads (86%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV56457819; called by muse, mutect2, varscan2
- CALD1 | c.1466C>A p.T489K (on ENST00000361675 / NM_033138.4; = p.T234K on NM_004342.7) | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.602); catalogued as COSV62645877; called by muse, mutect2, varscan2
- CARD6 | c.1948G>T p.A650S | Missense Mutation (SNP) | VAF 391/606 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV54564783; called by muse, mutect2, varscan2
- CARMIL3 | c.1874A>G p.H625R | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57725363; called by muse, mutect2, varscan2
- CASS4 | c.1722G>T p.K574N | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64385649; called by muse, mutect2
- CATSPERE | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63676664; called by muse, mutect2, varscan2
- CCDC40 | c.1290C>G p.I430M | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV53897687; called by muse, mutect2, varscan2
- CCDC54 | c.971_973del p.E324del | In Frame Del (DEL) | VAF 13/57 reads (23%) | catalogued as rs778479927; called by pindel, varscan2
- CCDC9B | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.297); catalogued as COSV66874899, COSV66875744; called by muse, mutect2, varscan2
- CCT7 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.942); catalogued as COSV57822079, COSV57823955; called by muse, varscan2
- CD34 | c.292G>T p.V98L | Missense Mutation (SNP) | VAF 157/348 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV60412071; called by muse, mutect2, varscan2
- CD4 | c.956-2A>T p.X319_splice | Splice Site (SNP) | VAF 12/38 reads (32%) | catalogued as COSV50589386; called by muse, mutect2, varscan2
- CD93 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs547369550, COSV55668148; called by muse, mutect2, varscan2
- CDH12 | c.2131A>C p.T711P | Missense Mutation (SNP) | VAF 25/196 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.378); catalogued as COSV66392964; called by muse, mutect2, varscan2
- CDH12 | c.568C>A p.P190T | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66392968; called by muse, mutect2, varscan2
- CDH4 | c.2098C>G p.L700V | Missense Mutation (SNP) | VAF 71/119 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV64644752; called by muse, mutect2, varscan2
- CENPF | c.4541G>T p.G1514V | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as COSV65273258; called by muse, mutect2, varscan2
- CEP192 | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1336741406, COSV58061107; called by muse, mutect2, varscan2
- CEP350 | c.4052G>C p.R1351T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV62608920; called by muse, mutect2, varscan2
- CFAP100 | c.743G>C p.R248T | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.412); catalogued as COSV61502562; called by muse, mutect2, varscan2
- CFAP47 | c.4466G>T p.G1489V | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV57971969; called by muse, mutect2, varscan2
- CFAP58 | c.2342G>T p.R781L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as COSV63833041; called by muse, mutect2
- CFAP61 | c.952-1G>T p.X318_splice | Splice Site (SNP) | VAF 40/105 reads (38%) | catalogued as COSV55622107; called by muse, mutect2, varscan2
- CFAP61 | c.2111C>A p.P704Q | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55622130; called by muse, mutect2, varscan2
- CFH | c.1523C>A p.S508Y | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV66412387; called by muse, mutect2, varscan2
- CFH | c.2158T>A p.S720T | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0.03); catalogued as COSV66406597; called by muse, mutect2, varscan2
- CHD6 | c.8138A>T p.D2713V | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV64688884; called by muse, mutect2, varscan2
- CHMP4B | c.483+1G>T p.X161_splice | Splice Site (SNP) | VAF 36/71 reads (51%) | catalogued as COSV54135344, COSV54137952; called by muse, mutect2, varscan2
- CLDN10 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as COSV54823530; called by muse, mutect2, varscan2
- CLIP4 | c.1823G>T p.W608L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV60748066; called by muse, mutect2, varscan2
- CNDP2 | c.1001G>T p.R334M | Missense Mutation (SNP) | VAF 24/31 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as COSV100158907; called by muse, mutect2, varscan2
- CNDP2 | c.1002G>T p.R334S | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.23); PolyPhen benign (0.025); catalogued as COSV100158911; called by muse, mutect2, varscan2
- CNGA1 | c.1657G>T p.A553S | Missense Mutation (SNP) | VAF 66/155 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV62053341; called by muse, mutect2
- CNKSR2 | c.88T>C p.Y30H | Missense Mutation (SNP) | VAF 24/32 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54251113; called by muse, mutect2, varscan2
- CNOT3 | c.387G>C p.T129= | Splice Region (SNP) | VAF 24/43 reads (56%) | catalogued as COSV55361055; called by muse, mutect2, varscan2
- CNPY1 | c.118G>T p.D40Y | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58786813; called by muse, mutect2, varscan2
- CNTNAP2 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV62244764; called by muse, mutect2, varscan2
- CNTNAP4 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1326923896, COSV56669182; called by muse, mutect2, varscan2
- CNTNAP5 | c.1631G>A p.C544Y | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70477372, COSV70508717; called by muse, mutect2, varscan2
- COL3A1 | c.3589T>A p.C1197S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.169); catalogued as COSV58583839; called by muse, mutect2, varscan2
- COL9A1 | c.1165C>A p.P389T | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV57880396; called by muse, mutect2, varscan2
- COX7B2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs373085380; called by muse, mutect2, varscan2
- CPD | c.2089G>A p.D697N | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as COSV56711328; called by muse, mutect2, varscan2
- CRYBG1 | c.2269G>T p.E757* | Nonsense Mutation (SNP) | VAF 22/24 reads (92%) | catalogued as COSV64811158, COSV64812480; called by muse, mutect2, varscan2
- CRYZ | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.63); catalogued as rs776408292, COSV61717168; called by muse, mutect2
- CSMD2 | c.3172G>T p.G1058C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53888507; called by muse, mutect2, varscan2
- CSMD3 | c.354C>A p.Y118* | Nonsense Mutation (SNP) | VAF 48/57 reads (84%) | catalogued as COSV52125086; called by muse, mutect2, varscan2
- CTNNA3 | c.1406G>C p.R469T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV65560596; called by muse, mutect2, varscan2
- CWH43 | c.2062C>A p.H688N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56936884; called by muse, mutect2, varscan2
- CYB5R1 | c.851T>A p.V284E | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61852350; called by muse, mutect2, varscan2
- CYP4F3 | c.1522del p.A508Qfs*12 | Frame Shift Del (DEL) | VAF 16/74 reads (22%) | catalogued as COSV99657896; called by mutect2, pindel, varscan2
- DAB2 | c.2107G>C p.D703H | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV57918403; called by muse, mutect2
- DCLK2 | c.612T>A p.S204R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV56210850; called by muse, mutect2, varscan2
- DDR2 | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369852; called by muse, mutect2, varscan2
- DDX11 | c.1210G>T p.G404C | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.011); catalogued as COSV52501020, COSV99300511; called by muse, mutect2, varscan2
- DIO1 | c.609C>A p.N203K | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59518764; called by muse, mutect2, varscan2
- DMXL1 | c.3248G>T p.C1083F | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60706472; called by muse, mutect2, varscan2
- DNAH2 | c.9951C>G p.F3317L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66717469; called by muse, mutect2, varscan2
- DNAH5 | c.8128G>T p.G2710C | Missense Mutation (SNP) | VAF 45/369 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54210217; called by muse, mutect2, varscan2
- DNAH7 | c.9528G>T p.K3176N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56781978; called by muse, mutect2, varscan2
- DNAH8 | c.3469G>T p.V1157L | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV59431290; called by muse, mutect2, varscan2
- DNAI4 | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as COSV64028422; called by muse, mutect2, varscan2
- DNAJC14 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.671); catalogued as COSV57912422; called by muse, mutect2, varscan2
- DOK5 | c.571A>G p.T191A | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770109660, COSV52817686; called by muse, mutect2, varscan2
- DOP1A | c.2338A>G p.T780A | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV52707794; called by muse, mutect2, varscan2
- DPYD | c.1369A>T p.N457Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV64592822; called by muse, mutect2, varscan2
- DPYS | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as COSV60907178; called by muse, mutect2, varscan2
- DSCAML1 | c.3712C>A p.R1238S (on ENST00000321322; = p.R1178S on NM_020693.4) | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.274); catalogued as COSV58384456, COSV58394794; called by muse, mutect2, varscan2
- DST | c.15542G>C p.R5181P (on ENST00000361203 / NM_001374722.1; = p.R2769P on NM_015548.5) | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55002147; called by muse, mutect2, varscan2
- DYSF | c.1437C>A p.Y479* | Nonsense Mutation (SNP) | VAF 41/139 reads (29%) | catalogued as COSV50277477; called by muse, mutect2, varscan2
- DYSF | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151064013, COSV50277551; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZANK1 | c.1048G>T p.A350S (on ENST00000262547 / NM_001099407.1; = p.A151S on NM_018152.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV52748592; called by muse, mutect2, varscan2
- EDRF1 | c.1303T>C p.Y435H (on ENST00000356792 / NM_001202438.2; = p.Y401H on NM_015608.2) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61765981; called by muse, mutect2, varscan2
- EHHADH | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 89/138 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV51628391; called by muse, mutect2, varscan2
- EIF4G1 | c.1948C>T p.R650W (on ENST00000346169 / NM_198241.3; = p.R454W on NM_004953.5) | Missense Mutation (SNP) | VAF 155/242 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as rs969580781, COSV59989637; called by muse, mutect2, varscan2
- EPB42 | c.10+3G>T | Splice Region (SNP) | VAF 33/120 reads (28%) | catalogued as COSV100281790; called by muse, mutect2, varscan2
- EPHB1 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs576710309, COSV101213156, COSV67655893; called by muse, mutect2, varscan2
- EPM2AIP1 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 53/98 reads (54%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.522); catalogued as COSV51615367; called by muse, mutect2, varscan2
- ERRFI1 | c.496G>A p.D166N | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV66310432; called by muse, mutect2, varscan2
- EXPH5 | c.4034A>T p.Q1345L | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as COSV56199688; called by muse, mutect2
- EYS | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 22/30 reads (73%) | catalogued as COSV60979157; called by muse, mutect2, varscan2
- FAIM2 | c.214A>T p.S72C | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as COSV57738166; called by muse, mutect2
- FAM171A1 | c.439G>T p.V147F | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs746749391, COSV65314260; called by muse, mutect2, varscan2
- FAM171B | c.1799C>A p.A600D | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as COSV100489172, COSV59007922; called by muse, mutect2, varscan2
- FAR2 | c.686C>A p.P229H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51729202; called by muse, mutect2, varscan2
- FAT3 | c.4073T>C p.I1358T | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV53086459; called by muse, mutect2, varscan2
- FAT3 | c.5540T>A p.F1847Y | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99971691; called by muse, mutect2, varscan2
- FAT3 | c.5541C>A p.F1847L | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99971692; called by muse, mutect2, varscan2
- FBN2 | c.6762C>G p.I2254M | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.708); catalogued as COSV52498318, COSV52498761; called by muse, mutect2, varscan2
- FGB | c.425C>G p.S142C | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV57417703, COSV57417883; called by muse, mutect2, varscan2
- FGF7 | c.83T>C p.I28T | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV51065647; called by muse, mutect2, varscan2
- FH | c.1165G>T p.G389W | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63817698; called by muse, mutect2, varscan2
- FMN2 | c.3322C>A p.P1108T | Missense Mutation (SNP) | VAF 55/254 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.429); catalogued as COSV60450089; called by muse, varscan2
- FOCAD | c.8A>G p.D3G | Missense Mutation (SNP) | VAF 31/37 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV58095139; called by muse, mutect2, varscan2
- FOXC2 | c.364C>A p.H122N | Missense Mutation (SNP) | VAF 74/89 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57445605; called by muse, mutect2, varscan2
- FSCB | c.189G>T p.K63N | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61217048, COSV61219539; called by muse, mutect2, varscan2
- FSHB | c.33T>A p.C11* | Nonsense Mutation (SNP) | VAF 42/46 reads (91%) | catalogued as COSV54221470; called by muse, mutect2, varscan2
- FXYD5 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.056); catalogued as COSV54342200; called by muse, mutect2, varscan2
- GABRA6 | c.583T>C p.S195P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50891751; called by muse, varscan2
- GAD2 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV52152251; called by muse, mutect2, varscan2
- GADL1 | c.724G>T p.D242Y | Missense Mutation (SNP) | VAF 105/210 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56976083, COSV56978021; called by muse, mutect2, varscan2
- GALNT13 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101224272, COSV67235955; called by muse, mutect2, varscan2
- GATA3 | c.918del p.R306Sfs*49 | Frame Shift Del (DEL) | VAF 38/108 reads (35%) | catalogued as COSV60522371; called by mutect2, pindel, varscan2
- GBF1 | c.2106+1G>T p.X702_splice (on ENST00000369983 / NM_001377137.1; = p.X701_splice on NM_004193.3) | Splice Site (SNP) | VAF 37/53 reads (70%) | catalogued as COSV64148471; called by muse, mutect2, varscan2
- GLB1L3 | c.634C>A p.Q212K | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101111135; called by muse, mutect2, varscan2
- GLI3 | c.1345C>T p.R449W | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.757); catalogued as rs769783770, COSV67886171; called by muse, mutect2, varscan2
- GNAL | c.901G>A p.E301K (on ENST00000269162 / NM_001142339.3; = p.E378K on NM_182978.4) | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as COSV52333049; called by muse, mutect2, varscan2
- GOLGA2 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 135/209 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as COSV60791730; called by muse, mutect2, varscan2
- GOLGB1 | c.3681G>T p.E1227D | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.11); catalogued as COSV61462785; called by muse, mutect2, varscan2
- GPD2 | c.738C>A p.Y246* | Nonsense Mutation (SNP) | VAF 45/109 reads (41%) | catalogued as COSV60096320; called by muse, mutect2, varscan2
- GPNMB | c.1172A>G p.N391S (on ENST00000381990 / NM_001005340.2; = p.N379S on NM_002510.3) | Missense Mutation (SNP) | VAF 73/336 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as COSV51697333; called by muse, mutect2, varscan2
- GPR149 | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as rs1290725918, COSV67668137; called by muse, mutect2, varscan2
- GPR174 | c.413G>T p.S138I | Missense Mutation (SNP) | VAF 86/96 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV52131744; called by muse, mutect2, varscan2
- GPR26 | c.472C>A p.L158M | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV52936180; called by muse, mutect2
- GPR4 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59916303, COSV59916377; called by muse, mutect2, varscan2
- GPR85 | c.772G>T p.G258C | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51782998; called by muse, mutect2, varscan2
- GPRIN3 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as rs1327588570, COSV60884365; called by muse, mutect2, varscan2
- GRAMD4 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV63032157; called by muse, mutect2, varscan2
- GRIK4 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV70800662; called by muse, mutect2, varscan2
- GRM7 | c.61C>G p.L21V | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.899); catalogued as COSV63133846; called by muse, mutect2, varscan2
- GTPBP4 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62550331; called by muse, mutect2, varscan2
- GUCA1C | c.85G>T p.E29* | Nonsense Mutation (SNP) | VAF 56/120 reads (47%) | catalogued as COSV99225113; called by muse, mutect2, varscan2
- GUCA1C | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 55/119 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99225116, COSV99227352; called by muse, mutect2, varscan2
- GUCY1A2 | c.1651A>C p.T551P | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56480500; called by muse, mutect2, varscan2
- GUCY1A2 | c.1267G>T p.G423C | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56480516; called by muse, mutect2, varscan2
- H2BC9 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 92/174 reads (53%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV55099510, COSV99079196; called by muse, mutect2, varscan2
- H3C3 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as COSV63550736; called by muse, mutect2, varscan2
- HAO1 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 84/139 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV66491374; called by muse, mutect2, varscan2
- HAPLN4 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52268751; called by muse, mutect2, varscan2
- HCK | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.342); catalogued as rs768447790, COSV52940932; called by muse, mutect2
- HCRTR2 | c.1057G>T p.V353L | Missense Mutation (SNP) | VAF 59/116 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.06); catalogued as rs76232306; called by muse, mutect2, varscan2
- HDAC7 | c.1672C>T p.R558W (on ENST00000427332; = p.R597W on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs764790473, COSV50406535; called by muse, mutect2, varscan2
- HDAC9 | c.1027G>C p.A343P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.462); catalogued as COSV67769159; called by muse, mutect2
- HEPHL1 | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs200108606, COSV59890083; called by muse, mutect2, varscan2
- HERC1 | c.722C>T p.T241I | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV71246597; called by muse, mutect2, varscan2
- HERC4 | c.1822G>T p.G608* | Nonsense Mutation (SNP) | VAF 19/27 reads (70%) | catalogued as COSV53269124; called by muse, mutect2, varscan2
- HLA-G | c.763G>T p.V255L | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.166); catalogued as COSV64405247, COSV64405301; called by muse, mutect2, varscan2
- HMCN1 | c.6890G>T p.S2297I | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as COSV54884187; called by muse, mutect2, varscan2
- HNF4A | c.1252T>A p.C418S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.966); catalogued as COSV57380592; called by muse, mutect2, varscan2
- HNRNPA1 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52935912; called by muse, mutect2, varscan2
- HOXA9 | c.344C>G p.T115R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1370995506, COSV100604268, COSV58655853; called by muse, mutect2, varscan2
- HOXB4 | c.672del p.N225Tfs*44 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | catalogued as COSV60178724; called by mutect2, pindel, varscan2
- HOXD11 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99983405; called by muse, mutect2, varscan2
- HPN | c.447C>G p.I149M | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV52882524; called by muse, mutect2, varscan2
- HPS5 | c.2461G>T p.V821L (on ENST00000349215 / NM_181507.2; = p.V707L on NM_007216.4) | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs373228021; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HSPA8 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as COSV57083035; called by muse, mutect2, varscan2
- HTR3A | c.260G>A p.R87Q | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.642); catalogued as rs747021831, COSV55468362; called by muse, mutect2, varscan2
- ICE1 | c.2098G>A p.E700K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV56820801; called by muse, mutect2, varscan2
- IFRD1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); catalogued as rs764321257, COSV50043760; called by muse, mutect2, varscan2
- IGF2R | c.5070C>G p.F1690L | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.832); catalogued as COSV63627027; called by muse, mutect2, varscan2
- IKZF1 | c.497T>A p.L166Q | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58782725; called by muse, mutect2, varscan2
- IMMT | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.78); catalogued as rs1327594106, COSV54485857; called by muse, mutect2, varscan2
- INSYN1 | c.749C>A p.S250* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV65837233; called by muse, mutect2, varscan2
- IQSEC1 | c.1273G>T p.G425C | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.735); catalogued as rs746716911, COSV56221927; called by muse, mutect2, varscan2
- ITIH5 | c.1147C>T p.L383F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV53672662; called by muse, mutect2
- KANK4 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62985759; called by muse, mutect2, varscan2
- KCNB2 | c.502G>C p.D168H | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV73048885, COSV73049315; called by muse, mutect2, varscan2
- KCNH6 | c.2309T>C p.M770T | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV59003954; called by muse, mutect2, varscan2
- KCNIP3 | c.479G>C p.R160P | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54672242; called by muse, mutect2, varscan2
- KCNJ4 | c.127A>G p.M43V | Missense Mutation (SNP) | VAF 89/184 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV57856429; called by muse, mutect2, varscan2
- KCNQ2 | c.2347G>T p.D783Y (on ENST00000359125 / NM_172107.4; = p.D755Y on NM_004518.6) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV60553191, COSV60554313; called by muse, mutect2, varscan2
- KIAA0753 | c.1237G>C p.E413Q | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as COSV63816935; called by muse, varscan2
- KIAA0753 | c.1165G>A p.E389K | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.23); catalogued as COSV63816938; called by muse, varscan2
- KIDINS220 | c.3118G>T p.V1040L | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.063); catalogued as COSV56751209; called by muse, mutect2, varscan2
- KIF16B | c.1768A>T p.M590L | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); catalogued as COSV61702550; called by muse, mutect2, varscan2
- KIF23 | c.2491G>A p.E831K (on ENST00000260363; = p.E727K on NM_004856.7) | Missense Mutation (SNP) | VAF 51/130 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as COSV52977919; called by muse, mutect2, varscan2
- KMT2C | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51405289; called by muse, mutect2, varscan2
- KMT2E | c.1041A>T p.K347N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV57570657; called by muse, mutect2, varscan2
- KMT2E | c.2221G>A p.E741K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV57578805; called by muse, mutect2, varscan2
- KMT5B | c.1747C>G p.P583A | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV58564290, COSV58564418, COSV58566347; called by muse, varscan2
- KMT5B | c.1655C>G p.S552C | Missense Mutation (SNP) | VAF 77/232 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as rs1307058162, COSV58564431; called by muse, varscan2
- KNL1 | c.5638A>G p.I1880V (on ENST00000346991 / NM_170589.5; = p.I1854V on NM_144508.5) | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as COSV61152280; called by muse, mutect2, varscan2
- KPRP | c.449T>G p.V150G | Missense Mutation (SNP) | VAF 83/220 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV64221181; called by muse, mutect2, varscan2
- KRTAP24-1 | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV61089122; called by muse, mutect2, varscan2
- L1CAM | c.289A>G p.I97V | Missense Mutation (SNP) | VAF 46/51 reads (90%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.461); catalogued as COSV62827245; called by muse, mutect2, varscan2
- L2HGDH | c.506A>T p.Q169L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as COSV55556456; called by muse, mutect2, varscan2
- L3MBTL1 | c.1327G>T p.A443S (on ENST00000418998 / NM_001377303.1; = p.A353S on NM_015478.7) | Missense Mutation (SNP) | VAF 126/210 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64228042; called by muse, mutect2, varscan2
- LAMA4 | c.1045C>A p.L349I (on ENST00000230538 / NM_001105206.3; = p.L342I on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/88 reads (70%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV57893095; called by muse, mutect2, varscan2
- LAMB3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs139547896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMC1 | c.1645G>T p.V549L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51134251, COSV51147113; called by muse, mutect2, varscan2
- LAMP1 | c.1003T>C p.S335P | Missense Mutation (SNP) | VAF 35/80 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58149042; called by muse, mutect2, varscan2
- LANCL2 | c.247G>C p.D83H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV54648168; called by muse, mutect2, varscan2
- LCLAT1 | c.625+1G>A p.X209_splice | Splice Site (SNP) | VAF 35/102 reads (34%) | catalogued as COSV58370982; called by muse, mutect2, varscan2
- LIPN | c.1091A>T p.Y364F | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.096); catalogued as COSV68383776; called by muse, mutect2, varscan2
- LMCD1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.713); catalogued as COSV50087561; called by muse, mutect2, varscan2
- LOX | c.468C>A p.N156K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as COSV99140739; called by muse, mutect2, varscan2
- LPO | c.1776G>A p.M592I | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1299546610, COSV51857364; called by muse, mutect2, varscan2
- LPP | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 240/385 reads (62%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.699); catalogued as COSV57082324; called by muse, mutect2, varscan2
- LRATD1 | c.502G>T p.E168* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV54472143, COSV54474056; called by muse, mutect2
- LRCH3 | c.1118A>G p.D373G | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV58390049; called by muse, mutect2, varscan2
- LRP1B | c.12761G>A p.S4254N | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs1375389625, COSV67196522; called by muse, mutect2, varscan2
- LRP1B | c.2564G>C p.R855T | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.033); catalogued as COSV63341633, COSV63341648; called by muse, mutect2, varscan2
- LRRC28 | c.552G>T p.E184D | Missense Mutation (SNP) | VAF 87/99 reads (88%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV57336276; called by muse, mutect2, varscan2
- LRRIQ1 | c.4189A>G p.K1397E | Missense Mutation (SNP) | VAF 47/53 reads (89%) | SIFT tolerated (0.42); PolyPhen benign (0.072); catalogued as COSV67827171; called by muse, mutect2, varscan2
- LRRN3 | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); catalogued as COSV100067970; called by muse, mutect2, varscan2
- LY75 | c.3528G>T p.W1176C | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715991; called by muse, mutect2, varscan2
- LY75 | c.3527G>T p.W1176L | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759824829, COSV99715993; called by muse, mutect2, varscan2
- MAGEA4 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV52340566; called by muse, mutect2, varscan2
- MAGEB4 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 11/11 reads (100%) | catalogued as COSV100854788, COSV64396813; called by muse, mutect2, varscan2
- MAGEC2 | c.392C>A p.P131Q | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.08); PolyPhen benign (0.269); catalogued as COSV99909399; called by muse, mutect2, varscan2
- MAGEC2 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 28/40 reads (70%) | SIFT tolerated (0.5); PolyPhen benign (0.082); catalogued as COSV99909401; called by muse, mutect2, varscan2
- MAGEL2 | c.3190C>A p.R1064S | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.274); catalogued as rs551493054, COSV58566263; called by muse, mutect2, varscan2
- MAGI2 | c.81G>T p.Q27H | Missense Mutation (SNP) | VAF 62/123 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV62639838; called by muse, mutect2, varscan2
- MAP3K13 | c.2797G>T p.E933* | Nonsense Mutation (SNP) | VAF 40/75 reads (53%) | catalogued as COSV53985061, COSV53995973; called by muse, mutect2, varscan2
- MCM5 | c.264G>T p.L88F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV53345330; called by muse, mutect2, varscan2
- MCPH1 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.088); catalogued as COSV60911127, COSV60915579; called by muse, mutect2, varscan2
- MEI1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV55900858; called by muse, mutect2, varscan2
- MFN2 | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 82/259 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52420879; called by muse, mutect2, varscan2
- MGAT4C | c.1108G>T p.G370W | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59830747; called by muse, mutect2, varscan2
- MIGA1 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.733); catalogued as rs146380219; called by muse, mutect2, varscan2
- MMRN1 | c.263C>G p.T88R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.282); catalogued as rs774290536, COSV53334836; called by muse, mutect2, varscan2
- MNDA | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 64/275 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV63740166; called by muse, mutect2, varscan2
- MOV10L1 | c.1363G>T p.A455S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV53168365; called by muse, mutect2, varscan2
- MROH1 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100395557; called by muse, mutect2, varscan2
- MRPL38 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as COSV58614160; called by muse, mutect2, varscan2
- MRPS15 | c.306G>C p.E102D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as rs774276263, COSV100910638, COSV64152197; called by muse, mutect2
- MRPS30 | c.748-1G>T p.X250_splice | Splice Site (SNP) | VAF 11/159 reads (7%) | catalogued as COSV50181560; called by muse, mutect2
- MST1R | c.418C>T p.Q140* | Nonsense Mutation (SNP) | VAF 37/103 reads (36%) | catalogued as rs1216259052, COSV56565834; called by muse, mutect2, varscan2
- MTIF3 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.204); catalogued as COSV66950058; called by muse, mutect2, varscan2
- MTOR | c.1787-1G>T p.X596_splice | Splice Site (SNP) | VAF 8/27 reads (30%) | catalogued as COSV63877369; called by muse, mutect2
- MUC16 | c.17657G>C p.W5886S | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); catalogued as COSV67452251; called by muse, mutect2, varscan2
- MUC17 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); catalogued as COSV60282508; called by muse, mutect2, varscan2
- MX1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55820686; called by muse, mutect2, varscan2
- MYBL1 | c.1826A>T p.Y609F | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.055); catalogued as COSV72919185; called by muse, mutect2, varscan2
- MYBL2 | c.129G>T p.R43S | Missense Mutation (SNP) | VAF 44/80 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.192); catalogued as COSV53828395; called by muse, mutect2, varscan2
- MYH11 | c.1017C>A p.S339R | Missense Mutation (SNP) | VAF 67/76 reads (88%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as COSV55545934; called by muse, mutect2, varscan2
- MYH2 | c.5669A>T p.E1890V | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.919); catalogued as COSV55433373; called by muse, mutect2
- MYH2 | c.2094G>C p.Q698H | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV55433387, COSV99820543; called by muse, mutect2, varscan2
- MYH3 | c.3182A>T p.K1061M | Missense Mutation (SNP) | VAF 51/62 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV56862115; called by muse, mutect2, varscan2
- MYH8 | c.464C>A p.P155H | Missense Mutation (SNP) | VAF 145/186 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101238771, COSV67961308; called by muse, mutect2, varscan2
- MYH9 | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53383099; called by muse, mutect2, varscan2
- MYLIP | c.1028A>G p.N343S | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV62766458; called by muse, mutect2, varscan2
- MYO16 | c.2086C>G p.Q696E | Missense Mutation (SNP) | VAF 64/79 reads (81%) | SIFT tolerated (0.06); PolyPhen benign (0.42); catalogued as COSV51781881; called by muse, mutect2, varscan2
- MYO6 | c.3530A>T p.Q1177L (on ENST00000369981; = p.Q1167L on NM_004999.4) | Missense Mutation (SNP) | VAF 66/80 reads (83%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); catalogued as COSV64117985; called by muse, mutect2, varscan2
- MYO9B | c.1146G>C p.E382D | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.083); catalogued as COSV68277664; called by muse, mutect2, varscan2
- MYOZ3 | c.15G>C p.E5D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); catalogued as COSV51739094; called by muse, mutect2, varscan2
- N6AMT1 | c.244G>C p.A82P | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58133925; called by muse, mutect2, varscan2
- NALCN | c.26G>A p.R9K | Missense Mutation (SNP) | VAF 79/95 reads (83%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as COSV51923142; called by muse, mutect2, varscan2
- NAMPT | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV104383065, COSV55994457; called by muse, mutect2, varscan2
- NAV2 | c.3262G>T p.G1088* (on ENST00000396087 / NM_001244963.2; = p.G1065* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 22/26 reads (85%) | catalogued as COSV60657215; called by muse, mutect2, varscan2
- NCAM1 | c.1490A>G p.Q497R (on ENST00000316851 / NM_181351.5; = p.Q487R on NM_000615.7) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as COSV57512317; called by muse, mutect2, varscan2
- NCAN | c.2407G>T p.G803* | Nonsense Mutation (SNP) | VAF 20/153 reads (13%) | catalogued as COSV53047908; called by muse, mutect2, varscan2
- NCKAP1L | c.2041C>A p.L681I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV53204395; called by muse, mutect2, varscan2
- NCOA1 | c.4066-1G>C p.X1356_splice | Splice Site (SNP) | VAF 81/323 reads (25%) | catalogued as COSV56040494; called by muse, mutect2, varscan2
- NCOA2 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71763653; called by muse, mutect2, varscan2
- NCOR2 | c.5187A>T p.R1729= | Splice Region (SNP) | VAF 75/85 reads (88%) | catalogued as COSV100656876; called by muse, mutect2, varscan2
- NCOR2 | c.5186G>T p.R1729L | Missense Mutation (SNP) | VAF 75/85 reads (88%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100656877; called by muse, mutect2, varscan2
- NCR1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 120/148 reads (81%) | SIFT tolerated (0.92); PolyPhen benign (0.023); catalogued as COSV52555784; called by muse, varscan2
- NEB | c.9458G>T p.W3153L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs1465012496, COSV50846379; called by muse, mutect2, varscan2
- NIBAN2 | c.689G>T p.C230F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV64825391; called by muse, mutect2, varscan2
- NID1 | c.260C>A p.P87H | Missense Mutation (SNP) | VAF 37/227 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1261570214, COSV51616285; called by muse, mutect2, varscan2
- NIN | c.3715G>C p.E1239Q | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55383036; called by muse, mutect2, varscan2
- NLRP12 | c.1747G>T p.V583F | Missense Mutation (SNP) | VAF 54/62 reads (87%) | SIFT deleterious (0.05); PolyPhen benign (0.107); catalogued as COSV60744549; called by muse, mutect2, varscan2
- NMD3 | c.574C>T p.H192Y | Missense Mutation (SNP) | VAF 50/84 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); catalogued as COSV63618303; called by muse, mutect2, varscan2
- NMNAT2 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55078068, COSV99818059; called by muse, varscan2
- NMT1 | c.138G>C p.L46F | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as COSV51958705; called by muse, mutect2
- NOL6 | c.3334G>T p.E1112* | Nonsense Mutation (SNP) | VAF 59/96 reads (61%) | catalogued as COSV53039868; called by muse, mutect2, varscan2
- NOL8 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV62637633; called by muse, mutect2, varscan2
- NOS1 | c.3647G>C p.C1216S | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57608281; called by muse, mutect2, varscan2
- NOTCH2 | c.2970G>C p.E990D | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV56684747; called by muse, mutect2, varscan2
- NPAP1 | c.2020C>G p.P674A | Missense Mutation (SNP) | VAF 61/125 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs901343402, COSV61505232, COSV61507875; called by muse, mutect2, varscan2
- NPY | c.234G>T p.L78F | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.448); catalogued as COSV54214452, COSV54214761; called by muse, mutect2, varscan2
- NPY2R | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV61527505; called by muse, mutect2, varscan2
- NTNG1 | c.1150T>C p.C384R | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); catalogued as COSV64268476; called by muse, mutect2, varscan2
- NTS | c.473G>T p.R158I | Missense Mutation (SNP) | VAF 110/133 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55455641; called by muse, mutect2, varscan2
- NUCB2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV60376713; called by muse, mutect2, varscan2
- NUCKS1 | c.220C>T p.H74Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.888); catalogued as COSV65652585; called by muse, mutect2, varscan2
- OBI1 | c.291A>T p.K97N | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV56144824; called by muse, mutect2, varscan2
- OLAH | c.626G>T p.G209V (on ENST00000378228 / NM_001039702.3; = p.G262V on NM_018324.3) | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65491747; called by muse, mutect2, varscan2
- OR10G7 | c.383C>A p.P128Q | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57866035; called by muse, mutect2
- OR13A1 | c.801C>A p.C267* | Nonsense Mutation (SNP) | VAF 39/75 reads (52%) | catalogued as COSV65572087; called by muse, mutect2, varscan2
- OR13F1 | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100594681; called by muse, mutect2, varscan2
- OR13G1 | c.710C>A p.T237K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62943629; called by muse, mutect2, varscan2
- OR14A16 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 58/296 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV62926250; called by muse, mutect2, varscan2
- OR2B3 | c.35T>C p.F12S | Missense Mutation (SNP) | VAF 42/64 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65850783, COSV65850910; called by muse, mutect2, varscan2
- OR2G6 | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV58575103, COSV58575269; called by muse, mutect2, varscan2
- OR2L13 | c.318G>T p.M106I | Missense Mutation (SNP) | VAF 105/435 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63549550; called by muse, mutect2, varscan2
- OR2M2 | c.122del p.G41Efs*90 | Frame Shift Del (DEL) | VAF 77/437 reads (18%) | catalogued as COSV62897771; called by mutect2, pindel, varscan2
- OR2M5 | c.422G>C p.C141S | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV63546920; called by muse, varscan2
- OR2T33 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 66/559 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV58814567; called by muse, mutect2, varscan2
- OR2T8 | c.245A>G p.D82G | Missense Mutation (SNP) | VAF 76/137 reads (55%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV60661826; called by muse, mutect2, varscan2
- OR4F15 | c.750C>G p.F250L | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV100173839, COSV59968502; called by muse, mutect2, varscan2
- OR4K14 | c.917G>C p.R306P | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.079); catalogued as COSV59292340, COSV59292361; called by muse, mutect2, varscan2
- OR4K5 | c.408G>C p.M136I | Missense Mutation (SNP) | VAF 79/611 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as COSV100262525, COSV60002621; called by muse, mutect2, varscan2
- OR4M1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 42/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60059954; called by muse, mutect2
- OR4N2 | c.620C>A p.T207K | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as COSV60050439, COSV60050464; called by muse, mutect2, varscan2
- OR51B2 | c.794A>C p.N265T | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV60916163; called by muse, mutect2, varscan2
- OR51L1 | c.698G>T p.R233L | Missense Mutation (SNP) | VAF 33/38 reads (87%) | SIFT tolerated (0.15); PolyPhen benign (0.042); catalogued as COSV58624167; called by muse, mutect2, varscan2
- OR5AN1 | c.731C>T p.S244F | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58321770; called by muse, mutect2, varscan2
- OR5L1 | c.595C>G p.L199V | Missense Mutation (SNP) | VAF 60/254 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.042); catalogued as COSV61733040; called by muse, mutect2, varscan2
- OR5R1 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs368362913, COSV56572291; called by muse, mutect2, varscan2
- OR7E24 | c.739C>A p.P247T | Missense Mutation (SNP) | VAF 16/21 reads (76%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV71702146, COSV71702359; called by muse, mutect2, varscan2
- OR8D1 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as COSV63441743, COSV63442931; called by mutect2, varscan2
- OR8J3 | c.680G>T p.R227M | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV56879699, COSV56884521; called by muse, mutect2, varscan2
- OR8K5 | c.657G>T p.M219I | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV57888120, COSV57890876; called by muse, mutect2, varscan2
- OVCH1 | c.2582C>A p.P861Q | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV58960447; called by muse, mutect2, varscan2
- PAK5 | c.641A>T p.D214V | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as COSV62023140; called by muse, mutect2, varscan2
- PARM1 | c.76C>G p.P26A | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as COSV56658628; called by muse, mutect2, varscan2
- PARM1 | c.181C>G p.H61D | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.08); catalogued as COSV100268052, COSV100268666; called by muse, mutect2, varscan2
- PARP16 | c.278A>T p.K93M | Missense Mutation (SNP) | VAF 104/257 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV56034807; called by muse, mutect2, varscan2
- PARP8 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen probably damaging (0.991); catalogued as rs1421501673, COSV55857271; called by mutect2, varscan2
- PCCA | c.1685C>T p.S562L | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0.04); catalogued as CM991023, COSV66189217, COSV66194414; called by muse, mutect2, varscan2
- PCDH15 | c.4631C>A p.T1544K | Missense Mutation (SNP) | VAF 53/89 reads (60%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.227); catalogued as COSV64679263; called by muse, mutect2, varscan2
- PCDH15 | c.1889G>T p.R630M | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57273258, COSV57391082; called by muse, mutect2, varscan2
- PCDHB14 | c.1898G>A p.R633H | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.812); catalogued as COSV99505551; called by muse, mutect2, varscan2
- PCDHGA1 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV65295383, COSV65296145; called by muse, mutect2, varscan2
- PCDHGA1 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.039); catalogued as COSV100965926, COSV65297686; called by muse, mutect2, varscan2
- PCDHGA2 | c.287G>T p.C96F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV53912902; called by muse, mutect2, varscan2
- PCDHGA2 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 81/204 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53912909; called by muse, mutect2, varscan2
- PCMT1 | c.425A>T p.D142V | Missense Mutation (SNP) | VAF 30/41 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66303076; called by muse, mutect2, varscan2
- PDGFRA | c.2618C>A p.T873N | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57265723; called by muse, mutect2, varscan2
- PEDS1 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV59015519; called by muse, mutect2, varscan2
- PFAS | c.2641G>T p.D881Y | Missense Mutation (SNP) | VAF 47/50 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58978977; called by muse, mutect2, varscan2
- PIK3CG | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.64); PolyPhen benign (0.009); catalogued as COSV100783011, COSV63246552; called by muse, mutect2, varscan2
- PJA2 | c.1531A>T p.S511C | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63272074; called by muse, mutect2, varscan2
- PKHD1 | c.5601-1G>T p.X1867_splice | Splice Site (SNP) | VAF 24/121 reads (20%) | catalogued as COSV61892029; called by muse, mutect2, varscan2
- PLAAT5 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV57136366; called by muse, mutect2, varscan2
- PLEKHM3 | c.1870G>C p.E624Q | Missense Mutation (SNP) | VAF 43/77 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV66815852; called by muse, mutect2, varscan2
- PODXL | c.846G>C p.Q282H (on ENST00000378555 / NM_001018111.3; = p.Q250H on NM_005397.4) | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV59868980; called by muse, mutect2, varscan2
- POLR3A | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.124); catalogued as COSV64930482; called by muse, mutect2, varscan2
- POU3F2 | c.946C>A p.L316M | Missense Mutation (SNP) | VAF 72/97 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100098968; called by muse, mutect2, varscan2
- POU3F2 | c.947T>A p.L316Q | Missense Mutation (SNP) | VAF 69/93 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100098973; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.647A>T p.E216V | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV53451346; called by muse, mutect2, varscan2
- PPM1L | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 153/224 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV55561758, COSV55565463; called by muse, mutect2, varscan2
- PPP1R1C | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.389); catalogued as COSV54715730, COSV54719056; called by muse, mutect2, varscan2
- PPP1R21 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 42/82 reads (51%) | SIFT tolerated (0.34); PolyPhen benign (0.112); catalogued as COSV54282750; called by muse, mutect2, varscan2
- PPP4R3A | c.1042C>G p.Q348E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.444); catalogued as COSV61503770, COSV61506840; called by muse, mutect2, varscan2
- PRDM9 | c.1757G>T p.G586V | Missense Mutation (SNP) | VAF 37/370 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57003688; called by muse, mutect2, varscan2
- PRICKLE1 | c.5C>T p.P2L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV61542279; called by muse, mutect2, varscan2
- PRKD1 | c.1991G>T p.G664V | Missense Mutation (SNP) | VAF 52/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59561529, COSV59568436; called by muse, mutect2, varscan2
- PRKG1 | c.1829G>T p.C610F | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV64767627, COSV64776800; called by muse, mutect2, varscan2
- PRMT5 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 89/156 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV53545118; called by muse, mutect2, varscan2
- PROM2 | c.549G>A p.M183I | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.059); catalogued as COSV58297150; called by muse, mutect2, varscan2
- PRSS1 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 36/147 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs141011596; called by muse, mutect2, varscan2
- PRUNE2 | c.4307G>T p.S1436I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.057); catalogued as COSV65038805; called by muse, mutect2, varscan2
- PSME4 | c.4973G>T p.R1658L | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV101122760, COSV66367242; called by muse, mutect2, varscan2
- PTBP2 | c.125G>T p.S42I (on ENST00000426398 / NM_001300986.2; = p.S34I on NM_021190.4) | Missense Mutation (SNP) | VAF 164/320 reads (51%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as COSV64623629; called by muse, mutect2, varscan2
- PTK7 | c.102C>A p.F34L | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57847161, COSV57851623; called by muse, mutect2, varscan2
- PTPRZ1 | c.1568_1569del p.V523Dfs*2 | Frame Shift Del (DEL) | VAF 36/160 reads (23%) | catalogued as rs1425489055; called by pindel, varscan2
- PXDNL | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV62481764; called by muse, mutect2, varscan2
- RAB37 | c.187G>T p.V63F | Missense Mutation (SNP) | VAF 82/219 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61193080; called by muse, mutect2, varscan2
- RAB3GAP2 | c.703G>C p.V235L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.163); catalogued as COSV52966868, COSV52966988; called by muse, mutect2, varscan2
- RAB41 | c.236T>G p.I79R (on ENST00000374473 / NM_001363807.1; = p.I78R on NM_001032726.3) | Missense Mutation (SNP) | VAF 57/69 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV52103420; called by muse, varscan2
- RAD9B | c.1124A>C p.K375T | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV63778626; called by muse, varscan2
- RAPGEF5 | c.1702G>T p.A568S (on ENST00000401957 / NM_001367602.2; = p.A871S on NM_012294.5) | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1228773947, COSV59780002; called by muse, mutect2, varscan2
- RARS2 | c.1690G>T p.A564S | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT tolerated (0.16); PolyPhen benign (0.34); catalogued as COSV65760362; called by muse, mutect2, varscan2
- RBM19 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs140564219; called by muse, mutect2, varscan2
- RBM28 | c.297G>C p.K99N | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.111); catalogued as COSV56164611; called by muse, mutect2
- RCN2 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs934551088, COSV58031153; called by muse, mutect2, varscan2
- RNPEPL1 | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54373838; called by muse, mutect2, varscan2
- ROBO2 | c.1350C>G p.S450R | Missense Mutation (SNP) | VAF 50/107 reads (47%) | SIFT tolerated (0.89); PolyPhen benign (0.101); catalogued as COSV59901287; called by muse, mutect2, varscan2
- ROCK2 | c.4010A>T p.Q1337L | Missense Mutation (SNP) | VAF 27/358 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59963855; called by muse, mutect2
- RPE65 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as rs61752887, CM057733, COSV52013951; ClinVar: not provided; called by muse, mutect2, varscan2
- RPL22L1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV55556694; called by muse, mutect2, varscan2
- RPS19 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 40/74 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV55743161; called by muse, mutect2, varscan2
- RRBP1 | c.2881G>C p.E961Q (on ENST00000377813 / NM_001365613.2; = p.E528Q on NM_004587.3) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); catalogued as COSV55697021; called by muse, mutect2, varscan2
- RTRAF | c.101A>G p.D34G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55562416; called by muse, mutect2, varscan2
- RYR2 | c.6268C>T p.R2090W | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1284802339, COSV63669937; called by muse, mutect2, varscan2
- RYR2 | c.9061C>A p.L3021I | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.849); catalogued as COSV63709634; called by muse, mutect2
- RYR2 | c.10514T>A p.V3505E | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63669948; called by muse, mutect2, varscan2
- RYR2 | c.12691C>A p.P4231T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1271445965, COSV63669962; called by muse, mutect2, varscan2
- RYR3 | c.6889C>A p.R2297S (on ENST00000389232; = p.R2298S on NM_001036.6) | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63109571; called by muse, mutect2, varscan2
- SCARB1 | c.457A>G p.M153V | Missense Mutation (SNP) | VAF 50/58 reads (86%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as COSV55544736; called by muse, mutect2, varscan2
- SCG2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 61/130 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756798030, COSV59539295; called by muse, mutect2, varscan2
- SCN11A | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV100182892, COSV56567158; called by muse, mutect2, varscan2
- SEC24C | c.3144+2T>A p.X1048_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | catalogued as COSV59544569; called by muse, mutect2, varscan2
- SEC24C | c.3170A>G p.K1057R | Missense Mutation (SNP) | VAF 73/195 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as COSV59540503; called by muse, mutect2, varscan2
- SEMA4D | c.2152C>T p.P718S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as rs921346331, COSV59391937; called by muse, mutect2, varscan2
- SERINC5 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV72595709; called by muse, mutect2, varscan2
- SERPINA4 | c.899G>T p.R300M | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54069144; called by muse, mutect2, varscan2
- SGCZ | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 52/69 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV66001834, COSV66030907; called by muse, mutect2, varscan2
- SH2D4B | c.368T>C p.I123T | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV57893563; called by muse, mutect2, varscan2
- SKAP1 | c.205G>C p.D69H | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV61144839; called by muse, mutect2, varscan2
- SLC27A6 | c.737C>A p.A246D | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.285); catalogued as COSV99322169; called by muse, mutect2, varscan2
- SLC2A14 | c.1336T>C p.S446P | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV61585802; called by muse, mutect2, varscan2
- SLC4A3 | c.2417C>A p.A806D | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV56092166; called by muse, mutect2, varscan2
- SLC5A4 | c.419G>C p.R140P | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56669102, COSV56673583; called by muse, mutect2, varscan2
- SLC5A7 | c.382G>T p.G128* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | catalogued as COSV50891559, COSV50900920; called by muse, mutect2, varscan2
- SLCO1B1 | c.457G>C p.A153P | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV104376739, COSV57008262; called by muse, mutect2, varscan2
- SLIT2 | c.3916G>T p.G1306C | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56564131; called by muse, mutect2, varscan2
- SLITRK1 | c.1042G>T p.D348Y | Missense Mutation (SNP) | VAF 45/56 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV65674618; called by muse, mutect2, varscan2
- SMAD9 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.15); PolyPhen benign (0.127); catalogued as COSV63204263; called by muse, mutect2, varscan2
- SMC3 | c.3134A>T p.Q1045L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62419330; called by muse, mutect2, varscan2
- SMYD1 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 64/266 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs143639398, COSV70224612, COSV70225024; called by muse, mutect2, varscan2
- SND1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61247962; called by muse, mutect2, varscan2
- SNX27 | c.217G>T p.E73* | Nonsense Mutation (SNP) | VAF 13/40 reads (33%) | catalogued as COSV64338257; called by muse, mutect2, varscan2
- SORCS1 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.427); catalogued as rs1238754962, COSV53848358, COSV53865482; called by muse, mutect2, varscan2
- SORL1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); catalogued as COSV52750850; called by mutect2, varscan2
- SPAG16 | c.943G>T p.D315Y | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59077400; called by muse, mutect2, varscan2
- SPATA5 | c.2318A>T p.N773I | Missense Mutation (SNP) | VAF 50/114 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56773159; called by muse, mutect2, varscan2
- SPEG | c.7973C>A p.S2658* | Nonsense Mutation (SNP) | VAF 26/53 reads (49%) | catalogued as COSV56678401; called by muse, mutect2, varscan2
- SPEN | c.2504C>G p.S835C | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV65358951, COSV65363069; called by muse, mutect2, varscan2
- SPIN3 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 64/74 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66529041, COSV66529484, COSV99059184; called by muse, mutect2, varscan2
- SPNS3 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 34/40 reads (85%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as COSV61069360, COSV61070363; called by muse, mutect2, varscan2
- SPON2 | c.167T>C p.F56S | Missense Mutation (SNP) | VAF 50/135 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52054449; called by muse, mutect2, varscan2
- SPTA1 | c.2898G>T p.Q966H | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV63750156; called by muse, mutect2
- SPTSSA | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV53294494; called by muse, mutect2, varscan2
- SRGAP3 | c.320G>T p.R107L | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64531272; called by muse, mutect2, varscan2
- SRSF6 | c.385T>A p.F129I | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.574); catalogued as COSV54828877; called by muse, mutect2
- SSH1 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 44/50 reads (88%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV58454976; called by muse, mutect2, varscan2
- SSR3 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV54020147; called by muse, mutect2
- ST18 | c.38G>T p.R13L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs368727956, COSV52506920; called by muse, mutect2, varscan2
- STAM2 | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as COSV55733792; called by muse, mutect2, varscan2
- STAT1 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.48); PolyPhen benign (0.023); catalogued as COSV63115287; called by muse, mutect2, varscan2
- STK32B | c.593G>C p.R198T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs776507984, COSV51476436; called by muse, mutect2, varscan2
- STOML3 | c.256G>T p.D86Y | Missense Mutation (SNP) | VAF 146/178 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65510166; called by muse, mutect2, varscan2
- SVEP1 | c.7319G>A p.C2440Y | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836738; called by muse, mutect2, varscan2
- SVEP1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.596); catalogued as COSV57045783; called by muse, mutect2, varscan2
- SYNE2 | c.1390G>C p.E464Q | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV59942453, COSV59970046; called by muse, mutect2, varscan2
- SYNE2 | c.16406C>A p.P5469Q | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.145); catalogued as COSV59942461; called by muse, mutect2, varscan2
- SYNE3 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs376779070, COSV62077729; called by muse, mutect2, varscan2
- SYNGAP1 | c.2239G>A p.V747I | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV53378998; called by muse, mutect2, varscan2
- SYNPR | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.031); catalogued as COSV55723604, COSV55729775; called by muse, mutect2, varscan2
- TAF8 | c.658A>C p.T220P | Missense Mutation (SNP) | VAF 294/492 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV65895777; called by muse, varscan2
- TANC1 | c.5288A>T p.Q1763L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV55095456; called by muse, mutect2, varscan2
- TAS2R19 | c.278A>G p.H93R | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV66828077; called by muse, mutect2, varscan2
- TBC1D4 | c.1080+1G>T p.X360_splice | Splice Site (SNP) | VAF 33/88 reads (38%) | catalogued as COSV100884837; called by muse, mutect2, varscan2
- TBC1D4 | c.1080G>A p.Q360= | Splice Region (SNP) | VAF 35/91 reads (38%) | catalogued as COSV66487828; called by muse, mutect2, varscan2
- TBXAS1 | c.842T>C p.M281T | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV54942109; called by muse, mutect2
- TCEAL3 | c.524C>A p.P175Q | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54580200; called by muse, mutect2
- TEX14 | c.1022G>T p.R341L (on ENST00000240361 / NM_001201457.2; = p.R335L on NM_031272.5) | Missense Mutation (SNP) | VAF 53/160 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV53613140; called by muse, mutect2, varscan2
- TEX14 | c.251+1G>T p.X84_splice | Splice Site (SNP) | VAF 44/68 reads (65%) | catalogued as COSV53613159; called by muse, mutect2, varscan2
- TEX26 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 47/54 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV66839573; called by muse, mutect2, varscan2
- THNSL2 | c.571+1G>T p.X191_splice | Splice Site (SNP) | VAF 14/68 reads (21%) | catalogued as rs1302616509, COSV59082206; called by muse, mutect2, varscan2
- THSD7A | c.2983G>C p.G995R | Missense Mutation (SNP) | VAF 79/383 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70260547, COSV70261638; called by muse, mutect2, varscan2
- TLR4 | c.2410C>G p.R804G (on ENST00000355622 / NM_138554.5; = p.R764G on NM_003266.4) | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV62922653; called by muse, mutect2, varscan2
- TM9SF2 | c.828G>T p.E276D | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.11); PolyPhen benign (0.098); catalogued as COSV64506358; called by muse, mutect2, varscan2
- TMEM176A | c.418T>A p.F140I | Missense Mutation (SNP) | VAF 86/162 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.378); catalogued as COSV50240367; called by muse, mutect2, varscan2
- TMEM33 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as COSV52561548; called by muse, mutect2, varscan2
- TMEM74 | c.263C>G p.S88* | Nonsense Mutation (SNP) | VAF 57/142 reads (40%) | catalogued as COSV52462702; called by muse, mutect2, varscan2
- TMEM81 | c.40G>T p.G14W | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.306); catalogued as COSV52703229; called by muse, mutect2, varscan2
- TMPRSS15 | c.1256A>T p.E419V | Missense Mutation (SNP) | VAF 55/167 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.043); catalogued as COSV53036165; called by muse, mutect2, varscan2
- TP53 | c.472del p.R158Afs*12 | Frame Shift Del (DEL) | VAF 49/79 reads (62%) | catalogued as CM004341, CM121763, COSV52677865, COSV52699654, COSV52778687; called by mutect2, pindel, varscan2
- TPD52 | c.576del p.K192Nfs*11 (on ENST00000379097 / NM_001025252.3; = p.K152Nfs*11 on NM_005079.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as COSV66951086; called by mutect2, pindel*, varscan2
- TPTE | c.517G>A p.D173N (on ENST00000618007 / NM_199261.4; = p.D155N on NM_199259.4) | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.115); catalogued as rs748367707; called by muse, mutect2, varscan2
- TPX2 | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 21/97 reads (22%) | catalogued as COSV55918012; called by muse, mutect2, varscan2
- TRAF3IP3 | c.1183C>A p.L395I | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.509); catalogued as COSV50550916; called by muse, mutect2
- TRIM25 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 214/391 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.122); catalogued as rs144571863, COSV57543532; called by muse, mutect2, varscan2
- TRIOBP | c.1327C>T p.P443S | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV60374957; called by muse, mutect2, varscan2
- TRIOBP | c.3823G>T p.D1275Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV60374964; called by muse, mutect2
- TRPA1 | c.174A>T p.R58S | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs375975650; called by muse, mutect2, varscan2
- TRPC6 | c.2259C>A p.Y753* | Nonsense Mutation (SNP) | VAF 18/54 reads (33%) | catalogued as COSV60251776; called by muse, mutect2, varscan2
- TRPM3 | c.964C>A p.Q322K (on ENST00000357533 / NM_001366142.2; = p.Q167K on NM_020952.6) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as COSV62468036; called by muse, mutect2, varscan2
- TSNAXIP1 | c.1338G>C p.K446N | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); catalogued as COSV54648500; called by muse, mutect2, varscan2
- TSPYL6 | c.984C>G p.I328M | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV57819400; called by muse, mutect2, varscan2
- TSSK6 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as rs1218726158, COSV53062835; called by muse, mutect2
- TTC27 | c.2208C>A p.C736* | Nonsense Mutation (SNP) | VAF 29/130 reads (22%) | catalogued as COSV58649577; called by muse, mutect2, varscan2
- TTN | c.96435G>C p.K32145N (on ENST00000591111; = p.K24721N on NM_003319.4) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | PolyPhen probably damaging (0.923); catalogued as COSV60298718; called by muse, mutect2, varscan2
- TTN | c.55277T>C p.I18426T (on ENST00000591111; = p.I11002T on NM_003319.4) | Missense Mutation (SNP) | VAF 70/196 reads (36%) | PolyPhen possibly damaging (0.447); catalogued as rs373690962, COSV60182929; called by muse, mutect2, varscan2
- TTN | c.31648C>A p.P10550T (on ENST00000591111; = p.P9623T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | PolyPhen benign (0.015); catalogued as COSV59932487; called by muse, mutect2, varscan2
- TTN | c.27694T>A p.L9232I (on ENST00000591111; = p.L8305I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/78 reads (49%) | PolyPhen benign (0.003); catalogued as COSV59932494; called by muse, mutect2, varscan2
- TTN | c.27379C>A p.Q9127K (on ENST00000591111; = p.Q8200K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | PolyPhen benign (0.003); catalogued as COSV59932502; called by muse, mutect2, varscan2
- TTN | c.10306C>G p.P3436A (on ENST00000591111; = p.P3390A on NM_003319.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | PolyPhen benign (0.014); catalogued as rs1209866675, COSV60298818; called by muse, mutect2, varscan2
- TUBA3E | c.926A>G p.H309R | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV56059782; called by muse, varscan2
- TYR | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as CM091282, COSV54471811; called by muse, mutect2, varscan2
- UBE3B | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV55097673; called by muse, mutect2, varscan2
- ULK4 | c.2437G>T p.E813* | Nonsense Mutation (SNP) | VAF 60/89 reads (67%) | catalogued as COSV57201853, COSV57213458; called by muse, mutect2, varscan2
- USF3 | c.3563A>T p.Q1188L | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.272); catalogued as COSV57070675; called by muse, mutect2, varscan2
- USH2A | c.14293G>A p.V4765I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as rs530395989, COSV56339098; called by muse, mutect2, varscan2
- USH2A | c.10751C>T p.A3584V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56339121; called by muse, mutect2, varscan2
- USH2A | c.5776+1G>T p.X1926_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as CS080750, COSV100229168; called by muse, mutect2, varscan2
- USP2 | c.63C>G p.H21Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.015); catalogued as COSV52731585; called by muse, mutect2, varscan2
- USP24 | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV53776950; called by mutect2, varscan2
- USP25 | c.1150G>T p.G384* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as rs1315719889, COSV53482028; called by muse, mutect2, varscan2
- USP31 | c.1400G>T p.G467V | Missense Mutation (SNP) | VAF 53/63 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54850228; called by muse, mutect2, varscan2
- UST | c.1166T>A p.I389N | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.083); catalogued as COSV66546106; called by muse, mutect2, varscan2
- VEPH1 | c.1937G>T p.W646L | Missense Mutation (SNP) | VAF 93/118 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62876785; called by muse, mutect2, varscan2
- VPS33B | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV60981516; called by muse, mutect2, varscan2
- VPS37A | c.881G>C p.R294T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61364359; called by muse, mutect2, varscan2
- VPS51 | c.1924G>T p.D642Y | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54206417; called by muse, mutect2, varscan2
- VTN | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV56874795; called by muse, mutect2, varscan2
- WAPL | c.945G>T p.M315I | Missense Mutation (SNP) | VAF 116/197 reads (59%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as COSV53933084; called by muse, mutect2, varscan2
- WDR77 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs1171177910, COSV52384787; called by muse, mutect2, varscan2
- YWHAB | c.173G>T p.R58L | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV62304010; called by muse, mutect2, varscan2
- ZBTB4 | c.2120G>A p.W707* | Nonsense Mutation (SNP) | VAF 31/53 reads (58%) | catalogued as COSV60977627; called by muse, mutect2, varscan2
- ZCWPW2 | c.203A>G p.Y68C | Missense Mutation (SNP) | VAF 100/142 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs942092881, COSV67497939; called by muse, mutect2, varscan2
- ZDBF2 | c.4954G>T p.D1652Y | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100984486, COSV65629477; called by muse, mutect2, varscan2
- ZDHHC1 | c.458G>T p.C153F | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62214713; called by muse, mutect2, varscan2
- ZFHX4 | c.6751C>A p.P2251T | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51455010, COSV51491910; called by muse, mutect2, varscan2
- ZNF100 | c.1151G>T p.R384L | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT tolerated (0.68); PolyPhen benign (0.009); catalogued as COSV59746791; called by muse, mutect2, varscan2
- ZNF134 | c.1257G>C p.Q419H | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); catalogued as COSV68696184; called by muse, mutect2, varscan2
- ZNF215 | c.450A>T p.K150N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV53494644; called by muse, mutect2, varscan2
- ZNF223 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 132/150 reads (88%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as rs746319751, COSV71571805; called by muse, mutect2, varscan2
- ZNF226 | c.1196G>C p.S399T | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV56196177; called by muse, mutect2, varscan2
- ZNF292 | c.1048A>G p.I350V | Missense Mutation (SNP) | VAF 37/45 reads (82%) | SIFT tolerated (0.34); PolyPhen benign (0.376); catalogued as rs1486267251, COSV60536598; called by muse, mutect2, varscan2
- ZNF333 | c.369G>C p.L123F | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); catalogued as COSV52885165; called by muse, varscan2
- ZNF337 | c.1082C>A p.S361* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV53320548; called by muse, mutect2, varscan2
- ZNF556 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 42/56 reads (75%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV56911250; called by muse, mutect2, varscan2
- ZNF598 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs374490857; called by muse, mutect2, varscan2
- ZNF648 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.362); catalogued as rs546993253, COSV60572506; called by muse, mutect2, varscan2
- ZNF675 | c.1600A>T p.K534* | Nonsense Mutation (SNP) | VAF 23/110 reads (21%) | catalogued as COSV63095293; called by muse, mutect2, varscan2
- ZNF99 | c.1766G>C p.G589A | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV68055074; called by muse, mutect2, varscan2
- ADA2 | c.21_22dup p.E8Vfs*24 | Frame Shift Ins (INS) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- BCO1 | c.1085_1086delinsT p.P362Lfs*14 | Frame Shift Del (DEL) | VAF 37/82 reads (45%) | called by pindel, varscan2*
- FAT2 | c.8791del p.L2931Wfs*101 | Frame Shift Del (DEL) | VAF 34/113 reads (30%) | called by mutect2, pindel, varscan2
- FREM1 | c.903_904delinsT p.V302Cfs*11 | Frame Shift Del (DEL) | VAF 44/97 reads (45%) | called by pindel, varscan2*
- FRG2 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FRYL | c.96dup p.E33* | Frame Shift Ins (INS) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- KIAA0232 | c.2663del p.G888Dfs*33 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- LRFN2 | c.1665_1676del p.R556_V559del | In Frame Del (DEL) | VAF 25/65 reads (38%) | called by mutect2, pindel, varscan2
- NF1 | c.4391del p.F1464Sfs*5 (on ENST00000358273 / NM_001042492.3; = p.F1443Sfs*5 on NM_000267.3) | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- OR2M7 | c.923del p.G308Afs*? | Frame Shift Del (DEL) | VAF 9/65 reads (14%) | called by mutect2, pindel, varscan2
- PCDHGA3 | c.2195dup p.L732Ffs*55 | Frame Shift Ins (INS) | VAF 21/59 reads (36%) | called by mutect2, pindel, varscan2
- PRAMEF14 | c.390T>A p.S130R | Missense Mutation (SNP) | VAF 59/278 reads (21%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRAMEF14 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 40/82 reads (49%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- SPANXN3 | c.174del p.K59Rfs*5 | Frame Shift Del (DEL) | VAF 35/45 reads (78%) | called by mutect2, pindel*, varscan2
- SPATA31A1 | c.1072A>T p.K358* | Nonsense Mutation (SNP) | VAF 126/168 reads (75%) | called by muse, mutect2, varscan2
- TCEAL6 | c.525dup p.G176Rfs*26 | Frame Shift Ins (INS) | VAF 46/71 reads (65%) | called by mutect2, pindel, varscan2
- USP6 | c.3679del p.A1227Pfs*17 | Frame Shift Del (DEL) | VAF 12/30 reads (40%) | called by mutect2, pindel, varscan2
- ZBTB40 | c.3483_3488del p.M1162_S1163del | In Frame Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel, varscan2
- A2ML1 | c.1569C>T p.T523= | Silent (SNP) | VAF 63/135 reads (47%) | catalogued as rs1455152222, COSV55287163; called by muse, mutect2, varscan2
- ABCB5 | c.159G>T p.L53= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV68855527; called by muse, mutect2, varscan2
- ABCB5 | c.1599C>A p.I533= (on ENST00000404938 / NM_001163941.2; = p.I88= on NM_178559.6) | Silent (SNP) | VAF 49/72 reads (68%) | catalogued as COSV51705118; called by muse, mutect2, varscan2
- ABCB8 | c.1614G>T p.L538= (on ENST00000297504 / NM_001282291.2; = p.L521= on NM_007188.5) | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as COSV99873804; called by muse, mutect2, varscan2
- ABHD3 | c.810T>C p.Y270= | Silent (SNP) | VAF 72/83 reads (87%) | catalogued as COSV56675885; called by muse, mutect2, varscan2
- ABL2 | c.2052A>G p.E684= (on ENST00000502732 / NM_007314.4; = p.E669= on NM_005158.5) | Silent (SNP) | VAF 84/291 reads (29%) | catalogued as COSV61011691; called by muse, mutect2, varscan2
- ACTN1 | c.1857G>T p.T619= | Silent (SNP) | VAF 18/33 reads (55%) | catalogued as COSV51989249, COSV51992960, COSV51993749; called by muse, mutect2, varscan2
- ACTN2 | c.711C>A p.T237= | Silent (SNP) | VAF 18/135 reads (13%) | catalogued as COSV63977819; called by muse, mutect2, varscan2
- ADAM19 | c.1932G>A p.R644= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV57424436; called by muse, mutect2, varscan2
- ADAM30 | c.951T>C p.Y317= | Silent (SNP) | VAF 35/207 reads (17%) | catalogued as rs759439950, COSV65560577; called by muse, mutect2, varscan2
- ADGRA1 | c.15G>A p.G5= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as COSV74142938; called by muse, mutect2
- ADRA1B | c.270C>T p.A90= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV60700810; called by muse, mutect2, varscan2
- AHNAK2 | c.11016G>C p.V3672= | Silent (SNP) | VAF 50/176 reads (28%) | catalogued as COSV60909981; called by muse, mutect2
- AMER3 | c.1020C>A p.S340= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as COSV58469588; called by muse, mutect2, varscan2
- ANAPC5 | c.1980A>G p.K660= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV55841796; called by muse, mutect2, varscan2
- ANK2 | c.11856A>C p.S3952= | Silent (SNP) | VAF 43/120 reads (36%) | catalogued as rs772699874, COSV99999810; called by muse, mutect2, varscan2
- ANKRD22 | c.222A>G p.R74= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV64237457; called by muse, mutect2, varscan2
- ANO7 | c.2547C>T p.I849= (on ENST00000274979; = p.I795= on NM_001370694.2) | Silent (SNP) | VAF 83/179 reads (46%) | catalogued as COSV51469471; called by muse, mutect2, varscan2
- APBB1IP | c.51A>T p.G17= | Silent (SNP) | VAF 44/153 reads (29%) | catalogued as COSV63301783; called by muse, mutect2, varscan2
- APP | c.999A>T p.T333= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV61004005; called by muse, mutect2, varscan2
- ARID3C | c.249C>A p.P83= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV66697671; called by muse, mutect2, varscan2
- ATP2B2 | c.558C>A p.I186= | Silent (SNP) | VAF 69/269 reads (26%) | catalogued as rs139130148, COSV59491520; called by muse, mutect2, varscan2
- BCAS3 | c.2388C>T p.R796= (on ENST00000390652 / NM_001353144.2; = p.R781= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/73 reads (53%) | catalogued as COSV66770958; called by muse, mutect2, varscan2
- CACNA1A | c.723A>T p.A241= | Silent (SNP) | VAF 24/36 reads (67%) | catalogued as COSV64192247; called by muse, mutect2, varscan2
- CALCRL | c.414A>G p.A138= | Silent (SNP) | VAF 43/126 reads (34%) | catalogued as COSV66476990; called by muse, mutect2, varscan2
- CCDC88A | c.1707C>T p.S569= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV55058081; called by muse, mutect2, varscan2
- CCNB1IP1 | c.348C>T p.G116= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs923496966, COSV62302509; called by muse, mutect2, varscan2
- CCT7 | c.882C>T p.P294= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs774738780, COSV57821527; called by muse, varscan2
- CDH23 | c.5565C>A p.P1855= | Silent (SNP) | VAF 61/109 reads (56%) | catalogued as COSV56452104; called by muse, mutect2, varscan2
- CDH26 | c.1242G>T p.L414= | Silent (SNP) | VAF 34/435 reads (8%) | catalogued as COSV54843892; called by muse, mutect2
- CENPJ | c.3543G>A p.V1181= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV55035872; called by muse, mutect2, varscan2
- CHRM1 | c.63T>A p.G21= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as COSV61006264; called by muse, mutect2, varscan2
- CHST15 | c.1659T>C p.D553= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV60565260; called by muse, mutect2, varscan2
- CLPB | c.249C>T p.L83= | Silent (SNP) | VAF 26/55 reads (47%) | catalogued as rs200845330, COSV53628020, COSV53632212, COSV99577898; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP5 | c.618C>A p.S206= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as rs367708864; called by muse, mutect2, varscan2
- COL19A1 | c.3099G>A p.R1033= | Silent (SNP) | VAF 16/18 reads (89%) | catalogued as COSV59567891; called by muse, mutect2, varscan2
- CSMD1 | c.9666G>T p.T3222= (on ENST00000520002; = p.T3221= on NM_033225.6) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs749126806, COSV59294241; called by muse, varscan2
- CSMD1 | c.2706G>T p.P902= (on ENST00000520002; = p.P901= on NM_033225.6) | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as COSV59294283; called by muse, mutect2, varscan2
- CSRNP2 | c.390A>G p.K130= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV57335219; called by muse, mutect2, varscan2
- CUTC | c.777C>A p.T259= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV65082172; called by muse, mutect2, varscan2
- DNAH3 | c.2457G>A p.K819= | Silent (SNP) | VAF 45/114 reads (39%) | catalogued as rs1384592894, COSV54509080, COSV99771271; called by muse, mutect2, varscan2
- DRD1 | c.420C>A p.A140= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV67104313; called by muse, mutect2, varscan2
- EPHX4 | c.696A>T p.I232= | Silent (SNP) | VAF 34/94 reads (36%) | catalogued as COSV64889121; called by muse, mutect2, varscan2
- EYA4 | c.1536C>A p.A512= (on ENST00000531901 / NM_001301013.1; = p.A506= on NM_004100.5) | Silent (SNP) | VAF 40/66 reads (61%) | catalogued as COSV62047489; called by muse, mutect2, varscan2
- FAIM2 | c.216C>T p.S72= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as COSV57738156; called by muse, mutect2
- FANCA | c.231G>C p.V77= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV66883452; called by muse, mutect2, varscan2
- FBXO16 | c.549A>G p.L183= | Silent (SNP) | VAF 47/52 reads (90%) | catalogued as COSV60774791; called by muse, mutect2, varscan2
- FMNL1 | c.2721G>A p.A907= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs764735089, COSV58958862; called by muse, mutect2, varscan2
- FOXC2 | c.363C>A p.R121= | Silent (SNP) | VAF 75/90 reads (83%) | catalogued as COSV100234103; called by muse, mutect2, varscan2
- FRG2C | c.660C>A p.A220= | Silent (SNP) | VAF 25/117 reads (21%) | called by muse, varscan2
- FRS2 | c.1239G>T p.R413= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100165810, COSV54723901; called by muse, mutect2, varscan2
- GAS2L3 | c.1464C>T p.H488= | Silent (SNP) | VAF 37/80 reads (46%) | catalogued as rs758286468, COSV57156407; called by muse, mutect2, varscan2
- GBP4 | c.1296G>A p.L432= | Silent (SNP) | VAF 90/256 reads (35%) | catalogued as COSV63253347; called by muse, mutect2, varscan2
- GLB1L3 | c.633C>A p.L211= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1204696910, COSV101111134; called by muse, mutect2, varscan2
- GOLGA5 | c.1461C>T p.G487= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV50835375; called by muse, mutect2
- GPR21 | c.588G>A p.V196= | Silent (SNP) | VAF 46/142 reads (32%) | catalogued as COSV65378859; called by muse, mutect2, varscan2
- GPSM1 | c.78G>A p.A26= | Silent (SNP) | VAF 16/24 reads (67%) | catalogued as rs372738428; called by muse, mutect2, varscan2
- GRIN2C | c.63G>A p.L21= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV53117362; called by muse, mutect2, varscan2
- GRM5 | c.1836C>T p.S612= | Silent (SNP) | VAF 20/60 reads (33%) | catalogued as COSV100555112, COSV59595342; called by muse, mutect2, varscan2
- HARS2 | c.999A>G p.T333= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as COSV51226853; called by muse, mutect2, varscan2
- HDAC5 | c.1038C>T p.L346= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV56817632; called by muse, mutect2, varscan2
- HDAC9 | c.1635G>C p.V545= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV67769173, COSV67775693; called by muse, mutect2, varscan2
- HECTD4 | c.1512G>A p.L504= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV66398541; called by muse, mutect2, varscan2
- HELT | c.408G>A p.P136= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs151053318; called by muse, mutect2, varscan2
- HOXD11 | c.147C>A p.S49= | Silent (SNP) | VAF 14/34 reads (41%) | catalogued as COSV99983409; called by muse, mutect2, varscan2
- ICE1 | c.3429G>A p.V1143= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV56820826; called by muse, mutect2, varscan2
- IFI44L | c.921C>T p.I307= | Silent (SNP) | VAF 65/219 reads (30%) | catalogued as COSV60726945; called by muse, mutect2, varscan2
- IFT172 | c.300T>A p.G100= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV53131044, COSV53140361; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.33G>T p.V11= | Silent (SNP) | VAF 45/316 reads (14%) | called by muse, mutect2, varscan2
- INO80D | c.1674C>T p.P558= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV68958329; called by muse, mutect2, varscan2
- INSR | c.4146C>T p.S1382= | Silent (SNP) | VAF 56/185 reads (30%) | catalogued as COSV57159153; called by muse, mutect2, varscan2
- INTS1 | c.6012G>A p.G2004= | Silent (SNP) | VAF 22/138 reads (16%) | catalogued as COSV67176653; called by muse, mutect2, varscan2
- ITGB4 | c.2697G>A p.L899= | Silent (SNP) | VAF 3/48 reads (6%) | catalogued as rs1299198218, COSV52331760; called by muse, mutect2
- ITSN2 | c.2145A>G p.K715= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV61944576; called by muse, mutect2, varscan2
- JUP | c.453C>G p.L151= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1028532952, COSV60279526; called by muse, mutect2
- KALRN | c.2992C>A p.R998= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV53755893; called by muse, mutect2, varscan2
- KCNK6 | c.585C>A p.L195= | Silent (SNP) | VAF 112/250 reads (45%) | catalogued as COSV54579103, COSV54581122; called by muse, mutect2, varscan2
- KCNN3 | c.576C>T p.S192= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs1432832525, COSV55213574; called by muse, mutect2, varscan2
- KIF21B | c.1647G>A p.E549= | Silent (SNP) | VAF 67/359 reads (19%) | catalogued as rs1414689344, COSV59754027; called by muse, mutect2, varscan2
- KIRREL1 | c.846G>A p.T282= | Silent (SNP) | VAF 54/308 reads (18%) | catalogued as COSV63285802; called by muse, mutect2, varscan2
- KLHL4 | c.1258C>A p.R420= | Silent (SNP) | VAF 22/23 reads (96%) | catalogued as COSV64139892; called by muse, mutect2, varscan2
- KMT5B | c.2337C>T p.I779= | Silent (SNP) | VAF 47/191 reads (25%) | catalogued as COSV58564400; called by muse, mutect2, varscan2
- KRTAP9-4 | c.237C>A p.P79= | Silent (SNP) | VAF 100/208 reads (48%) | catalogued as COSV61897656; called by muse, mutect2, varscan2
- KSR2 | c.1764G>C p.A588= | Silent (SNP) | VAF 81/98 reads (83%) | catalogued as COSV56668089; called by muse, mutect2, varscan2
- LGALS9 | c.882G>A p.L294= (on ENST00000395473 / NM_009587.3; = p.L262= on NM_002308.4) | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV56348210; called by muse, mutect2, varscan2
- LGR6 | c.537C>A p.V179= (on ENST00000367278 / NM_001017403.1; = p.V127= on NM_021636.3) | Silent (SNP) | VAF 33/85 reads (39%) | catalogued as COSV55152852, COSV99707836; called by muse, mutect2, varscan2
- LRFN5 | c.1692C>A p.T564= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV53246927; called by muse, mutect2, varscan2
- LRP1 | c.11538C>T p.L3846= | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as COSV54504603, COSV99675504; called by muse, mutect2, varscan2
- LRP1B | c.12093T>A p.A4031= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as COSV67196531; called by muse, mutect2, varscan2
- LRP1B | c.1497G>T p.R499= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV67218428, COSV67266573; called by muse, mutect2, varscan2
- LRRN3 | c.594T>C p.N198= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV100067966; called by muse, mutect2, varscan2
- LTBP1 | c.4422C>T p.P1474= (on ENST00000404816 / NM_206943.4; = p.P1148= on NM_000627.4) | Silent (SNP) | VAF 46/138 reads (33%) | catalogued as COSV55376688, COSV55378832; called by muse, mutect2, varscan2
- LTBP1 | c.4698C>A p.P1566= (on ENST00000404816 / NM_206943.4; = p.P1240= on NM_000627.4) | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV55384577; called by muse, mutect2, varscan2
- MAP3K21 | c.2190G>T p.L730= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV64041241; called by muse, mutect2, varscan2
- MARCHF10 | c.960G>C p.G320= | Silent (SNP) | VAF 192/447 reads (43%) | catalogued as COSV60885759; called by muse, mutect2, varscan2
- MARK2 | c.2280C>T p.L760= (on ENST00000402010 / NM_001039469.2; = p.L696= on NM_004954.5) | Silent (SNP) | VAF 39/140 reads (28%) | catalogued as COSV56849594; called by muse, mutect2, varscan2
- MAST4 | c.7209G>A p.A2403= (on ENST00000403625 / NM_001164664.2; = p.A2214= on NM_015183.3) | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV55118427; called by muse, varscan2
- MEP1A | c.312C>T p.L104= | Silent (SNP) | VAF 38/148 reads (26%) | catalogued as rs540101823, COSV57918524; called by muse, mutect2, varscan2
- MUC16 | c.27741A>C p.T9247= | Silent (SNP) | VAF 20/101 reads (20%) | catalogued as COSV67452246; called by muse, mutect2, varscan2
- MUC16 | c.39C>A p.P13= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as COSV67452255; called by muse, mutect2, varscan2
- MYH14 | c.3810G>A p.R1270= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV51812214; called by muse, mutect2, varscan2
- MYH6 | c.5658G>A p.E1886= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV59305091; called by muse, mutect2, varscan2
- MYH8 | c.3993C>A p.A1331= | Silent (SNP) | VAF 98/127 reads (77%) | catalogued as COSV67961300; called by muse, mutect2, varscan2
- MYO10 | c.3591C>T p.C1197= | Silent (SNP) | VAF 41/303 reads (14%) | catalogued as rs754365346, COSV57018152; called by muse, mutect2, varscan2
- NAA80 | c.540G>T p.V180= (on ENST00000417393 / NM_001200018.2; = p.V202= on NM_012191.4) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV56496990; called by muse, mutect2, varscan2
- NAPEPLD | c.618G>A p.E206= | Silent (SNP) | VAF 63/128 reads (49%) | catalogued as COSV58521494; called by muse, mutect2, varscan2
- NCDN | c.477G>A p.L159= | Silent (SNP) | VAF 25/121 reads (21%) | catalogued as COSV57843107; called by muse, mutect2, varscan2
- NEO1 | c.777C>A p.V259= | Silent (SNP) | VAF 44/56 reads (79%) | catalogued as COSV56068665, COSV56074070; called by muse, mutect2, varscan2
- NEU3 | c.1152C>T p.P384= | Silent (SNP) | VAF 54/105 reads (51%) | catalogued as COSV53635900; called by muse, mutect2, varscan2
- NPR3 | c.819G>T p.V273= | Silent (SNP) | VAF 119/175 reads (68%) | catalogued as COSV54085307; called by muse, mutect2, varscan2
- NRG1 | c.1581G>T p.T527= (on ENST00000405005 / NM_013964.5; = p.T532= on NM_013956.5) | Silent (SNP) | VAF 17/29 reads (59%) | catalogued as COSV55173730, COSV55177457; called by muse, mutect2, varscan2
- NTRK2 | c.810T>C p.N270= | Silent (SNP) | VAF 91/188 reads (48%) | catalogued as COSV52857079; called by muse, mutect2, varscan2
- OR11G2 | c.870C>T p.Y290= | Silent (SNP) | VAF 45/157 reads (29%) | catalogued as rs376290528, COSV100639985, COSV62131923; called by muse, mutect2, varscan2
- OR13F1 | c.318C>T p.A106= | Silent (SNP) | VAF 13/33 reads (39%) | catalogued as COSV100594683; called by muse, mutect2, varscan2
- OR2C3 | c.693A>T p.S231= | Silent (SNP) | VAF 38/167 reads (23%) | catalogued as COSV63574601; called by muse, mutect2, varscan2
- OR2L2 | c.477A>T p.T159= | Silent (SNP) | VAF 59/288 reads (20%) | catalogued as COSV63559692; called by muse, mutect2, varscan2
- OR51B2 | c.522T>A p.R174= | Silent (SNP) | VAF 25/53 reads (47%) | catalogued as COSV60915823, COSV60917071; called by muse, mutect2, varscan2
- OR5D18 | c.765C>G p.T255= | Silent (SNP) | VAF 32/107 reads (30%) | catalogued as COSV61738430, COSV61738451; called by muse, mutect2, varscan2
- OSMR | c.2139C>T p.F713= | Silent (SNP) | VAF 206/369 reads (56%) | catalogued as COSV57082082, COSV99952607; called by muse, mutect2, varscan2
- OTOP2 | c.231C>A p.I77= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as COSV58880991; called by muse, mutect2, varscan2
- P2RY8 | c.867C>T p.D289= | Silent (SNP) | VAF 28/39 reads (72%) | catalogued as COSV67176838; called by muse, mutect2, varscan2
- PACS1 | c.1587C>T p.S529= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as rs370986656, COSV57696821, COSV57697768; called by muse, mutect2, varscan2
- PCDHA3 | c.1854G>A p.A618= | Silent (SNP) | VAF 47/103 reads (46%) | catalogued as rs1554122551, COSV63538759; called by muse, mutect2, varscan2
- PCDHB13 | c.36G>A p.R12= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV99506738; called by muse, varscan2
- PDE2A | c.1167C>G p.L389= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV57803710; called by muse, mutect2, varscan2
- PDGFRB | c.63C>A p.L21= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as COSV55809446, COSV99940817; called by muse, mutect2, varscan2
- PEX11A | c.696A>T p.A232= | Silent (SNP) | VAF 203/223 reads (91%) | catalogued as COSV55583019; called by muse, mutect2, varscan2
- PGBD2 | c.426G>T p.V142= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as rs374536227, COSV61399769; called by muse, mutect2, varscan2
- PIP | c.339C>G p.V113= | Silent (SNP) | VAF 124/168 reads (74%) | catalogued as COSV52120106; called by muse, mutect2, varscan2
- PKD1L1 | c.1779C>T p.A593= | Silent (SNP) | VAF 22/107 reads (21%) | catalogued as COSV56976200; called by muse, mutect2, varscan2
- PLAT | c.1458C>G p.V486= | Silent (SNP) | VAF 49/121 reads (40%) | catalogued as COSV54274587; called by muse, mutect2, varscan2
- PLCB4 | c.1143A>C p.T381= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV53795885; called by muse, mutect2, varscan2
- PLCE1 | c.5436G>T p.V1812= | Silent (SNP) | VAF 45/259 reads (17%) | catalogued as COSV53341357; called by muse, mutect2, varscan2
- PLPPR3 | c.807C>T p.I269= (on ENST00000520876 / NM_001270366.2; = p.I297= on NM_024888.2) | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs781702457, COSV62459053; called by muse, mutect2, varscan2
- POM121L12 | c.162C>A p.P54= | Silent (SNP) | VAF 71/103 reads (69%) | catalogued as COSV101374881, COSV68692443; called by muse, mutect2, varscan2
- PPP1R17 | c.207G>T p.P69= | Silent (SNP) | VAF 44/250 reads (18%) | catalogued as COSV59610798; called by muse, mutect2, varscan2
- PPP1R18 | c.1770G>T p.L590= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV51294824; called by muse, mutect2, varscan2
- PRAP1 | c.237T>C p.G79= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV53369309; called by muse, mutect2, varscan2
- PRPF40B | c.636C>T p.P212= (on ENST00000380281; = p.P206= on NM_012272.3) | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as rs1288464202, COSV56058160; called by muse, mutect2, varscan2
- PRSS37 | c.150G>T p.V50= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV63339158; called by muse, mutect2, varscan2
- PRSS58 | c.18C>T p.L6= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as COSV73488482; called by muse, varscan2
- PSMG2 | c.324C>G p.S108= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs760762445, COSV58287835; called by muse, mutect2, varscan2
- PTCHD4 | c.219G>A p.L73= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV59779792; called by muse, mutect2, varscan2
- PTPRA | c.867G>T p.G289= | Silent (SNP) | VAF 86/170 reads (51%) | catalogued as COSV53779242, COSV53789620; called by mutect2, varscan2
- RHBDD1 | c.297G>T p.L99= | Silent (SNP) | VAF 38/132 reads (29%) | catalogued as COSV58125173; called by muse, mutect2, varscan2
- RNF133 | c.720A>T p.R240= | Silent (SNP) | VAF 71/210 reads (34%) | catalogued as COSV57353551; called by muse, mutect2, varscan2
- RP9 | c.549G>A p.E183= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV51806302, COSV99778056; called by muse, mutect2, varscan2
- RYR1 | c.2520C>T p.G840= | Silent (SNP) | VAF 79/154 reads (51%) | catalogued as COSV62091771; called by muse, mutect2, varscan2
- SLC22A11 | c.696G>T p.T232= | Silent (SNP) | VAF 35/54 reads (65%) | catalogued as COSV57252241; called by muse, mutect2, varscan2
- SLC27A6 | c.738T>G p.A246= | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV99322176; called by muse, mutect2, varscan2
- SLC6A5 | c.2379G>T p.L793= | Silent (SNP) | VAF 134/154 reads (87%) | catalogued as rs201726001, COSV54224583; called by muse, mutect2, varscan2
- SOX10 | c.624G>A p.K208= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV62806225; called by muse, mutect2, varscan2
- SPINT4 | c.120C>A p.P40= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54142486; called by muse, mutect2, varscan2
- SPTLC1 | c.9C>T p.T3= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV52763116; called by muse, mutect2, varscan2
- SSR3 | c.252C>G p.L84= | Silent (SNP) | VAF 21/141 reads (15%) | catalogued as COSV54020151; called by muse, mutect2, varscan2
- SYK | c.1617C>T p.Y539= | Silent (SNP) | VAF 57/179 reads (32%) | catalogued as rs201650753, COSV65325775, COSV65330072; called by muse, mutect2, varscan2
- TAL1 | c.957T>C p.P319= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as COSV53745617; called by muse, mutect2, varscan2
- TCOF1 | c.3654C>A p.A1218= (on ENST00000377797 / NM_001135243.1; = p.A1141= on NM_000356.4) | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as COSV60353406; called by muse, mutect2, varscan2
- TCP10L | c.132T>G p.T44= | Silent (SNP) | VAF 8/150 reads (5%) | catalogued as COSV55829612; called by muse, mutect2
- TERT | c.2664C>T p.V888= | Silent (SNP) | VAF 14/340 reads (4%) | catalogued as COSV99721232; called by muse, mutect2
- TEX45 | c.1197G>T p.R399= | Silent (SNP) | VAF 22/22 reads (100%) | catalogued as rs1255752040, COSV64462866; called by muse, mutect2, varscan2
- TFAP2B | c.813C>T p.V271= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV53825777; called by muse, mutect2
- THAP9 | c.1083G>A p.L361= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as COSV56355866; called by muse, mutect2, varscan2
- THEMIS2 | c.1320C>T p.Y440= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs765639848, COSV61077359; called by muse, mutect2, varscan2
- THSD7A | c.831C>A p.R277= | Silent (SNP) | VAF 49/196 reads (25%) | catalogued as rs377308966, COSV70261643; called by muse, mutect2, varscan2
- TLCD5 | c.138C>T p.L46= (on ENST00000375095 / NM_001198671.2; = p.L68= on NM_174926.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as COSV58754704; called by muse, mutect2, varscan2
- TMEM132E | c.2322G>T p.V774= (on ENST00000321639; = p.V864= on NM_001304438.2) | Silent (SNP) | VAF 20/50 reads (40%) | catalogued as COSV58695331; called by muse, mutect2, varscan2
- TMEM169 | c.63C>T p.L21= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV55264512; called by muse, mutect2, varscan2
- TMOD1 | c.867C>T p.N289= | Silent (SNP) | VAF 10/61 reads (16%) | catalogued as COSV52251957; called by muse, mutect2, varscan2
- TMTC3 | c.1776G>T p.L592= | Silent (SNP) | VAF 21/48 reads (44%) | catalogued as COSV57122704; called by muse, mutect2, varscan2
- TRIM2 | c.1311C>T p.R437= (on ENST00000437508; = p.R464= on NM_015271.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 18/52 reads (35%) | catalogued as rs141510470; called by muse, mutect2, varscan2
- TRPV3 | c.420G>A p.V140= | Silent (SNP) | VAF 46/96 reads (48%) | catalogued as COSV56789376; called by muse, mutect2, varscan2
- TSPAN13 | c.297G>T p.L99= | Silent (SNP) | VAF 22/114 reads (19%) | catalogued as COSV50437793; called by muse, mutect2, varscan2
- TTC23L | c.969C>T p.F323= | Silent (SNP) | VAF 22/195 reads (11%) | catalogued as COSV72205785; called by muse, mutect2, varscan2
- TTN | c.24795A>G p.L8265= (on ENST00000591111; = p.L7338= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1256143330, COSV59932509; called by muse, mutect2, varscan2
- UBA2 | c.114C>T p.L38= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV55826432; called by muse, mutect2
- UBQLN2 | c.483G>T p.S161= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as COSV57739197; called by muse, mutect2, varscan2
- UNC13C | c.2511T>A p.S837= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV52850595; called by muse, mutect2, varscan2
- UNC5B | c.402C>T p.S134= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as COSV58975265; called by muse, mutect2, varscan2
- UNCX | c.339C>T p.T113= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as rs781509694, COSV100310287, COSV60332931, COSV60333656; called by muse, mutect2, varscan2
- UPF3A | c.1306C>A p.R436= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as COSV60896019; called by muse, mutect2, varscan2
- VN1R1 | c.180C>A p.I60= | Silent (SNP) | VAF 31/32 reads (97%) | catalogued as rs1478228184, COSV58090803, COSV58091361; called by muse, mutect2, varscan2
- XRN1 | c.4212G>A p.K1404= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV53809062; called by muse, mutect2, varscan2
- XRRA1 | c.1644C>A p.L548= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ZEB1 | c.609C>T p.S203= | Silent (SNP) | VAF 39/102 reads (38%) | catalogued as COSV58038859; called by muse, mutect2, varscan2
- ZNF43 | c.426G>A p.Q142= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs34211771, COSV61683217; called by muse, mutect2, varscan2
- ZNF518B | c.2853G>T p.V951= | Silent (SNP) | VAF 60/122 reads (49%) | catalogued as COSV58721685; called by muse, mutect2, varscan2
- ZP1 | c.861C>T p.V287= | Silent (SNP) | VAF 76/261 reads (29%) | catalogued as rs1439768269, COSV53923540; called by muse, mutect2
- ZSCAN1 | c.264C>A p.G88= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as COSV56607854, COSV99991693; called by muse, mutect2, varscan2
- AQP1 | c.*361T>A | 3'UTR (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100311064; called by muse, mutect2
- CDKL1 | chr14:50397620 C>G | 5'Flank (SNP) | VAF 5/33 reads (15%) | catalogued as rs774971006; called by muse, mutect2
- CDV3 | c.*1G>A | 3'UTR (SNP) | VAF 42/95 reads (44%) | catalogued as COSV99394152; called by muse, mutect2, varscan2
- CHCHD2P9 | n.328C>A | RNA (SNP) | VAF 9/29 reads (31%) | called by muse, mutect2, varscan2
12 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 12 other) are not listed here.
